Gene-level copy-number profile of tumor specimen TCGA-HU-A4GF-01A from TCGA case TCGA-HU-A4GF, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 69.1 years (25,223 days).
Specimen TCGA-HU-A4GF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.0e1d8c84-577f-448d-a688-94239cddbb30.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4GF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44f45d16-1f39-45dd-a7d7-d9a73f997e3f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 3,735; copy number 2: 32,441; copy number 3: 17,699; copy number 4: 4,146; copy number 5: 688; copy number 6: 588; copy number 7: 85; copy number 8: 8; copy number 9: 43; copy number 10: 22; copy number 11: 19; copy number 13: 42; copy number 14: 157; copy number 15: 60; copy number 21: 34; copy number 23: 4; copy number 30: 11; copy number 34: 9; copy number 40: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4GF-01A-11D-A24C-01): tumor purity 0.66, ploidy 2.52, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,059,361–175,115,242, 2 genes: EEF1B2P8, NAALADL2-AS3.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr13:41,566,835–41,961,120, 1 gene (within-gene range 0–3): VWA8.
- chr13:41,807,677–41,807,973, 1 gene: RN7SL515P.
- chr20:15,021,553–15,022,958, 2 genes: RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,775 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,296,982–31,704,319, 16 genes, copy number 5 (within-gene range 3–5): ZCCHC17, AL451070.1, FABP3, SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1, HCRTR1, PEF1, PEF1-AS1, AC114488.2, COL16A1.
- chr3:101,724,593–101,997,926, 8 genes, copy number 8 (within-gene range 4–8): CEP97, NXPE3, AC020651.1, NFKBIZ, AC020651.2, LINC02085, Y_RNA, AC106712.1.
- chr3:143,265,222–143,848,485, 1 gene, copy number 5 (within-gene range 4–5): SLC9A9.
- chr3:143,381,338–146,606,216, 26 genes, copy number 5: SLC9A9-AS2, GAPDHP47, ST13P15, AC073358.1, AC107421.1, DIPK2A, RNA5SP144, AC011592.1, LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr5:58,198–2,262,023, 79 genes, copy number 6 (broad region; genes not listed).
- chr5:4,436,850–39,572,639, 519 genes, copy number 5–10 (broad region; genes not listed).
- chr6:4,049,434–4,189,806, 7 genes, copy number 6: FAM217A, C6orf201, ECI2, AL136309.3, ECI2-DT, AL136309.2, AL136309.1.
- chr6:45,328,157–45,664,349, 1 gene, copy number 5 (within-gene range 4–5): RUNX2.
- chr6:45,573,346–63,616,361, 225 genes, copy number 5–7 (broad region; genes not listed).
- chr10:37,523,011–38,689,068, 36 genes, copy number 6 (within-gene range 2–6): TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3.
- chr10:69,801,880–71,077,810, 26 genes, copy number 6 (within-gene range 3–6): COL13A1, LINC02636, MACROH2A2, AIFM2, TYSND1, SAR1A, CALM2P2, RPS25P9, PPA1, NPFFR1, LRRC20, CEP57L1P1, EIF4EBP2, NODAL, AC022532.1, PALD1, YY1P1, PRF1, ADAMTS14, TBATA, RPS26P40, SGPL1, PCBD1, AC073176.2, AC073176.1, LINC02622.
- chr10:71,217,224–71,381,423, 3 genes, copy number 6: UNC5B-AS1, SLC29A3, AL359183.1.
- chr10:71,508,153–71,511,873, 1 gene, copy number 6: CDH23-AS1.
- chr10:124,397,303–124,617,888, 5 genes, copy number 7: OAT, NKX1-2, AL445237.1, LHPP, RPS10P18.
- chr12:50,743,568–51,346,679, 29 genes, copy number 5: Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP, BIN2, CELA1.
- chr13:80,697,177–81,017,737, 2 genes, copy number 5 (within-gene range 3–5): AL590807.1, ARF4P4.
- chr14:20,556,093–21,724,321, 79 genes, copy number 7–11 (broad region; genes not listed).
- chr17:31,709,568–32,997,877, 58 genes, copy number 5–15: AC007923.2, RNU6-1134P, GPR160P2, AC007923.1, AC004253.2, COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3.
- chr17:33,052,107–33,131,743, 3 genes, copy number 15: AC003687.1, AC008133.2, AC008133.1.
- chr17:36,684,754–37,056,871, 11 genes, copy number 13: AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5.
- chr17:37,140,611–37,163,139, 3 genes, copy number 13: AC244093.1, HMGB1P24, AC244093.2.
- chr17:39,401,793–41,836,260, 157 genes, copy number 14 (within-gene range 2–14) (broad region; genes not listed).
- chr17:54,609,249–55,421,924, 13 genes, copy number 23–34: AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD.
- chr17:55,526,964–55,842,830, 5 genes, copy number 40 (within-gene range 2–40): AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP.
- chr17:61,942,605–62,968,549, 34 genes, copy number 21: MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3, AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3, AC005972.3, MIR633, TRMT112P3.
- chr17:73,334,384–73,949,906, 11 genes, copy number 30 (within-gene range 2–30): SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1, AC137735.3, AC137735.2.
- chr19:27,638,483–27,984,984, 14 genes, copy number 13: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1.
- chr19:28,294,093–29,093,031, 20 genes, copy number 10: AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1.
- chr19:29,811,991–32,676,597, 45 genes, copy number 6–13 (within-gene range 2–13): CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P.
- chr20:34,955,810–47,356,889, 338 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,734. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
